FM case AD15482 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/e7160222-e7d2-4631-a0f1-f5990343bc66

Male, 67.3 years: Glioma, malignant (ICD-O-3 9380/3) of the nervous system; metastasis biopsied or resected from the brain. Tumor nuclei on the sequenced sample's slide: 63% (pathologist estimate recorded by GDC). Sample type: Metastatic.
